TARGET case TARGET-15-PAVFTF — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/52878bcc-6200-4d7a-a2f8-110f9f8401d0

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 2.0 years (746 days); Days to last follow up: 364 days.

Biospecimens (3 samples)
- Samples TARGET-15-PAVFTF-09A, TARGET-15-PAVFTF-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-PAVFTF-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
